TARGET case TARGET-00-BM5759 — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/37c8b584-f0ed-45b4-b5ea-3c5b34fa79c3

Biospecimens (1 sample)
- Sample TARGET-00-BM5759-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
